Somatic mutation profile of cancer-model specimen HCM-CSHL-0151-C50-85A (3D Organoid, passage 13; aliquot HCM-CSHL-0151-C50-85A-01D-A87L-36), derived from the primary tumor of HCMI case HCM-CSHL-0151-C50, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 42.3 years (15,434 days).
Specimen HCM-CSHL-0151-C50-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 13.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 28d4c6a8-88be-467b-9ef5-649843a63b62.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0151-C50-10A (Blood Derived Normal), aliquot HCM-CSHL-0151-C50-10A-01D-A87L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f3babb8c-6602-4d22-bb6b-46bd9aced049

The open-access MAF lists 51 somatic variants for this specimen: 34 protein-altering or splice-affecting, 13 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 13, Intron 3, Nonsense Mutation 2, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAH8 | c.10951C>T p.R3651* | Nonsense Mutation (SNP) | VAF 151/299 reads (51%) | catalogued as rs769929539, COSV59438495; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AMER3 | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 193/378 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as rs377467515, COSV58467280; called by muse, mutect2, varscan2
- ATG9B | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 176/327 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.334); catalogued as COSV52506630; called by muse, mutect2, varscan2
- CATSPERD | c.490C>T p.R164C | Missense Mutation (SNP) | VAF 73/203 reads (36%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.83); catalogued as rs371002531; called by muse, mutect2, varscan2
- CBFB | c.119G>A p.R40H | Missense Mutation (SNP) | VAF 184/184 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV51998016; called by muse, mutect2, varscan2
- GNL3 | c.1220C>T p.T407I | Missense Mutation (SNP) | VAF 109/239 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.019); catalogued as COSV56476711; called by muse, mutect2, varscan2
- GPATCH2L | c.718G>C p.G240R | Missense Mutation (SNP) | VAF 103/219 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55049422; called by muse, mutect2, varscan2
- GRIA4 | c.146T>C p.F49S | Missense Mutation (SNP) | VAF 90/393 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.145); catalogued as COSV56884195; called by muse, mutect2, varscan2
- H2AB1 | c.47G>A p.R16Q | Missense Mutation (SNP) | VAF 40/41 reads (98%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV100371533; called by mutect2, varscan2
- KAT5 | c.326C>T p.P109L | Missense Mutation (SNP) | VAF 253/495 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.07); catalogued as rs1479110981, COSV57729302; called by muse, mutect2
- MAN2B2 | c.2326G>A p.E776K | Missense Mutation (SNP) | VAF 87/326 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.237); catalogued as COSV53452999, COSV53453849; called by muse, mutect2, varscan2
- MDGA1 | c.1499G>A p.R500Q | Missense Mutation (SNP) | VAF 222/481 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.413); catalogued as COSV51803166; called by muse, mutect2, varscan2
- MED24 | c.1797C>A p.F599L | Missense Mutation (SNP) | VAF 59/116 reads (51%) | SIFT tolerated (0.71); PolyPhen benign (0.081); catalogued as COSV62419186; called by muse, mutect2, varscan2
- MESP2 | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 241/516 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as rs771745973; called by muse, mutect2, varscan2
- MPND | c.685C>T p.R229W | Missense Mutation (SNP) | VAF 100/260 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as rs746276763; called by muse, mutect2, varscan2
- NFATC1 | c.412G>A p.D138N | Missense Mutation (SNP) | VAF 80/331 reads (24%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.891); catalogued as rs775904780; called by muse, mutect2, varscan2
- PIK3CA | c.3172A>C p.I1058L | Missense Mutation (SNP) | VAF 154/310 reads (50%) | SIFT tolerated (0.57); PolyPhen benign (0.006); catalogued as COSV55879683, COSV55899901; called by muse, mutect2, varscan2
- TOPORS | c.68C>T p.P23L | Missense Mutation (SNP) | VAF 199/423 reads (47%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as rs1280716906; called by muse, varscan2
- ZNF469 | c.6116C>T p.A2039V (on ENST00000437464; = p.A2067V on NM_001367624.2) | Missense Mutation (SNP) | VAF 283/285 reads (99%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1453934715; called by muse, mutect2, varscan2
- ABCB11 | c.3337G>A p.G1113R | Missense Mutation (SNP) | VAF 279/563 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AGAP3 | c.1904T>G p.V635G (on ENST00000622464; = p.V671G on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 152/332 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- KIAA1549L | c.2951A>G p.N984S (on ENST00000321505; = p.N1281S on NM_012194.3) | Missense Mutation (SNP) | VAF 24/246 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2
- MAGEB5 | c.86C>T p.S29L | Missense Mutation (SNP) | VAF 225/508 reads (44%) | SIFT tolerated (0.37); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MAP4 | c.512C>T p.P171L | Missense Mutation (SNP) | VAF 46/281 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- PIK3CA | c.313_318del p.V105_G106del | In Frame Del (DEL) | VAF 105/237 reads (44%) | called by mutect2, pindel, varscan2
- PROCR | c.568G>A p.V190M | Missense Mutation (SNP) | VAF 137/259 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- RNF128 | c.748G>C p.D250H (on ENST00000255499 / NM_194463.2; = p.D224H on NM_024539.3) | Missense Mutation (SNP) | VAF 22/397 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.067); called by muse, mutect2
- RNF19A | c.2200T>G p.S734A | Missense Mutation (SNP) | VAF 82/315 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- SLC29A1 | c.1048G>T p.V350L | Missense Mutation (SNP) | VAF 32/227 reads (14%) | SIFT tolerated (0.66); PolyPhen benign (0.009); called by muse, varscan2
- SPIRE2 | c.217G>T p.V73F | Missense Mutation (SNP) | VAF 48/181 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- TMEM94 | c.2281C>T p.Q761* | Nonsense Mutation (SNP) | VAF 16/241 reads (7%) | called by muse, mutect2
- TRIL | c.2384C>T p.A795V | Missense Mutation (SNP) | VAF 238/532 reads (45%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- TTYH1 | c.88C>G p.P30A | Missense Mutation (SNP) | VAF 38/471 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.223); called by muse, mutect2
- USP46 | c.462G>A p.M154I | Missense Mutation (SNP) | VAF 41/335 reads (12%) | SIFT tolerated (0.87); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANTXR2 | c.1278C>T p.I426= | Silent (SNP) | VAF 209/442 reads (47%) | called by muse, mutect2, varscan2
- C4orf47 | c.858T>C p.S286= | Silent (SNP) | VAF 97/207 reads (47%) | called by muse, mutect2, varscan2
- CCDC141 | c.4494G>A p.V1498= | Silent (SNP) | VAF 138/309 reads (45%) | called by muse, mutect2, varscan2
- FANCA | c.1293C>T p.F431= | Silent (SNP) | VAF 230/230 reads (100%) | called by muse, mutect2, varscan2
- GATA5 | c.1071C>T p.P357= | Silent (SNP) | VAF 17/355 reads (5%) | catalogued as rs556416810; called by muse, mutect2
- IGHV3OR16-13 | c.240A>T p.A80= | Silent (SNP) | VAF 132/418 reads (32%) | called by muse, mutect2, varscan2
- NFAT5 | c.3648C>A p.G1216= | Silent (SNP) | VAF 11/224 reads (5%) | catalogued as rs948856598; called by muse, mutect2
- NOP53 | c.966C>T p.A322= | Silent (SNP) | VAF 248/468 reads (53%) | catalogued as rs562399482, COSV55882674; called by muse, mutect2, varscan2
- PMVK | c.541T>C p.L181= | Silent (SNP) | VAF 163/662 reads (25%) | called by muse, mutect2, varscan2
- SLFNL1 | c.1146G>A p.A382= | Silent (SNP) | VAF 148/308 reads (48%) | catalogued as rs201980070; called by muse, mutect2, varscan2
- TGFB1I1 | c.1155C>T p.F385= (on ENST00000394863 / NM_001042454.3; = p.F368= on NM_015927.4) | Silent (SNP) | VAF 73/737 reads (10%) | catalogued as rs770198654; called by muse, mutect2, varscan2
- UMODL1 | c.168G>A p.T56= | Silent (SNP) | VAF 41/381 reads (11%) | catalogued as rs373713727; called by muse, mutect2, varscan2
- VPS13C | c.7468C>T p.L2490= (on ENST00000644861 / NM_020821.3; = p.L2447= on NM_017684.5) | Silent (SNP) | VAF 47/233 reads (20%) | catalogued as rs141078479; called by muse, mutect2, varscan2
- KCNQ1 | c.1514+23548C>T | Intron (SNP) | VAF 132/275 reads (48%) | called by muse, mutect2, varscan2
- MICAL3 | c.2241+1543C>T | Intron (SNP) | VAF 233/481 reads (48%) | catalogued as rs766701812; called by muse, mutect2, varscan2
- NRSN1 | c.190-4566A>G | Intron (SNP) | VAF 72/289 reads (25%) | called by muse, mutect2, varscan2
- URI1 | c.*506C>T | 3'UTR (SNP) | VAF 153/326 reads (47%) | called by muse, mutect2, varscan2
